Somatic mutation profile of tumor specimen 0DVJOO from CCDI case PBCMSF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 9.8 years (3,569 days).
Specimen 0DVJOO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c94a5adb-8593-4f4f-aaa9-809d6bdb73b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9846e3f-f5ec-4d9a-829e-6642f8aa6a3e

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 26/560 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- CENPC | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 92/1074 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs756546956; called by muse, mutect2
- CADPS2 | c.3353G>C p.S1118T | Missense Mutation (SNP) | VAF 56/1348 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCNU1 | c.2332-1G>A p.X778_splice | Splice Site (SNP) | VAF 29/804 reads (4%) | called by muse, mutect2
- EPGN | c.420G>A p.L140= | Silent (SNP) | VAF 36/1220 reads (3%) | catalogued as rs1046955324; called by muse, mutect2
- FBXO48 | c.438G>A p.G146= | Silent (SNP) | VAF 42/907 reads (5%) | catalogued as rs1004343330; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/240 reads (12%) | called by muse, varscan2
